Surgical pathology report (de-identified scan), TCGA case TCGA-2Z-A9J3, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Z-A9J3-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: M Service: Received:

Reported:
Submitting Physicians:
Pathologist:
Intraop Pathologist:
Performing Physician:

CLINICAL HISTORY:
NONE GIVEN.

PREOPERATIVE DIAGNOSIS:
RIGHT KIDNEY MASS.

SPECIMEN TYPE(S):
A: RIGHT KIDNEY AND ADRENAL

FINAL DIAGNOSIS:
A. RIGHT KIDNEY AND RIGHT ADRENAL GLAND, RADICAL NEPHRECTOMY:
Renal cell carcinoma, papillary type II. (see Key Pathological Findings)
Adrenal gland, free of malignancy.
Pathologic stage: pT2 NX MX.

KEY PATHOLOGICAL FINDINGS

Tumor type: Renal cell carcinoma, papillary type II
Nuclear grade: III
Pattern of growth: Solid
Tumor size: 17.5 cm
Renal capsule invasion: Not identified
Invasion of Gerota's fascia: Not applicable
Renal vein invasion: Not identified
Surgical margins: Free of malignancy
Ureter margin: Free of malignancy
Vascular margin: Free of malignancy
Angiolymphatic invasion: Not identified
Perineural invasion: Not identified
Non-neoplastic kidney: Rare glomerulosclerosis, mild arterial sclerosis and focal interstitial fibrosis
Adrenal gland: Free of malignancy
Lymph nodes: Not applicable

I, M.D. the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically Signed out by

OTHER RELATED CLINICAL DATA:
NA

GROSS DESCRIPTION:

A. Specimen A is received fresh labeled "right kidney and adrenal". The specimen consists of a 213g kidney surrounded by an irregular fibroadipose tissue envelope measuring 23.0 x 15.0 x 11.5 cm. Prior to sectioning the specimen, the perinephric fat is inked. On sectioning there is an ovoid tumor mass located in the superior-medial aspect of the kidney. The tumor mass measures 17.5 x 15.0 x 15.0 cm. The tumor is variegated tan-yellow to tan-brown with multiple areas of necrosis and hemorrhage. The tumor does not invade the calyceal system and does not invade the renal sinus. The tumor does not penetrate through the inner capsule to involve

ICD-O-3
Carcinoma, papillary renal cell
Site @ Kidney NOS C64.9 826063
QW 4/28/14

[page 2 of 2]
the perinephric fat. The tumor is well demarcated from the uninvolved renal parenchyma. Additional tumor nodules are not present. The kidney parenchyma is tan to tan-red. The corticomedullary junction is well demarcated and measures 1.0 cm in thickness. The medullary cords, calyces and renal pelvis are unremarkable. Attached to the kidney is a 7-cm length of ureter which is unremarkable. The renal artery reveals mild atherosclerotic changes. The renal vein is grossly unremarkable. Sectioning the perihilar fibroadipose tissue, no lymph nodes are isolated. The adrenal gland is attached to the specimen, measuring 6.0 x 2.5 x 1.0 cm. The adrenal gland is serially sectioned to reveal unremarkable cut surface. Lesions or masses are not grossly identified. Representative fresh tissue is submitted to the Tissue Procurement Laboratory. Representative sections are submitted as follows:

- A1: Ureter vein and artery as margin of resection.
- A2: Tumor in relation to inked perinephric fat margin of resection.
- A3: Tumor in relation to renal parenchyma.
- A4-A8: Tumor.
- A9: Uninvolved renal parenchyma.
- A10: Section of adrenal gland.

Dual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file 925661ca-b9bc-4dbc-921c-e4bf7ada6530 (TCGA-2Z-A9J3.A037BD51-D79B-425E-9E0F-120BA6F0EBBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).